Gene-level copy-number profile of tumor specimen ALCH-B1X1-TTP1-A from ALCHEMIST case ALCH-B1X1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,288 days).
Specimen ALCH-B1X1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fe1ffd57-e24e-4dff-ad3c-be1308d0118e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1X1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/42e12578-8dc7-4088-a8b0-503cbb9d5935

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 7,392; copy number 2: 51,348; copy number 3: 60; copy number 4: 91; copy number 5: 6.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:176,647,387–176,659,054, 1 gene: TSPAN17.
- chr7:98,214,624–98,252,232, 1 gene: TECPR1.
- chr12:131,894,622–131,929,351, 3 genes (within-gene range 0–2): ULK1, AC131009.4, AC131009.1.
- chr14:93,067,452–93,072,152, 1 gene (within-gene range 0–2): ITPK1-AS1.
- chr15:78,759,206–78,811,464, 1 gene (within-gene range 0–2): ADAMTS7.
- chr17:30,702,504–30,790,908, 6 genes (within-gene range 0–2): RN7SL316P, SUZ12P1, AC127024.7, AC127024.3, AC127024.2, AC127024.8.
- chr18:78,795,612–78,796,672, 1 gene: AC044873.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,269,491–38,300,322, 6 genes, copy number 5 (within-gene range 2–5): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.

Autosomal genes at a single copy (total copy number 1): 4,540. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
